Somatic mutation profile of tumor specimen TCGA-XF-A9T3-01A (aliquot TCGA-XF-A9T3-01A-11D-A42E-08) from TCGA case TCGA-XF-A9T3, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 69.9 years (25,532 days).
Specimen TCGA-XF-A9T3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07f6896b-c252-4bb1-9677-a1e65cd928d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9T3-10A (Blood Derived Normal), aliquot TCGA-XF-A9T3-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/baab3e38-e59a-4e6e-b805-df9381d69bfd

The open-access MAF lists 472 somatic variants for this specimen: 331 protein-altering or splice-affecting, 129 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 284, Silent 129, Nonsense Mutation 19, Splice Site 13, Frame Shift Del 9, Intron 8, Splice Region 2, In Frame Del 2, RNA 2, 5'Flank 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.188G>C p.R63P | Missense Mutation (SNP) | VAF 29/131 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV55742044, COSV99028634; called by muse, mutect2, varscan2
- CREBBP | c.4508A>G p.Y1503C | Missense Mutation (SNP) | VAF 35/97 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587783497, CM085345, CM1414257, COSV52117486, COSV52122031, COSV52142946; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.2301A>C p.L767F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705638, COSV66706950; called by muse, mutect2, varscan2
- ERCC2 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55538701; called by muse, mutect2, varscan2
- TP53 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 16/36 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1511132, COSV52737174, COSV52760297, COSV52868891; called by muse, mutect2, varscan2
- AASS | c.1290C>G p.D430E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV62792300; called by muse, mutect2, varscan2
- ABCB7 | c.1519A>G p.S507G (on ENST00000373394 / NM_001271696.3; = p.S508G on NM_004299.6) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53724325; called by muse, mutect2, varscan2
- ABCC4 | c.3280C>G p.P1094A | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); catalogued as COSV65319180; called by muse, mutect2, varscan2
- ABCG2 | c.859T>C p.Y287H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs1430718813, COSV52950064; called by muse, mutect2, varscan2
- ABHD3 | c.1178T>C p.V393A | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs947509675, COSV56678750; called by muse, mutect2
- ACTN1 | c.2386A>T p.M796L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV51998514; called by muse, mutect2, varscan2
- ADCK1 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.129); catalogued as rs781704374, COSV53081375; called by muse, mutect2, varscan2
- ADGRL2 | c.2498A>G p.H833R (on ENST00000370717 / NM_001366005.1; = p.H820R on NM_012302.4) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV54691985; called by muse, mutect2, varscan2
- AFF4 | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.114); catalogued as COSV54793726, COSV54800342; called by muse, mutect2, varscan2
- AFG3L2 | c.1793C>G p.P598R | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52317820; called by muse, mutect2
- AGBL5 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448861312, COSV59938158; called by muse, mutect2, varscan2
- AHSG | c.443A>G p.D148G | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV56609564; called by muse, mutect2, varscan2
- AKAP14 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100538264, COSV57630143, COSV57631417; called by muse, mutect2, varscan2
- AKR1C3 | c.487A>G p.I163V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1443743492, COSV65911288; called by muse, mutect2, varscan2
- AKR1C4 | c.49C>G p.P17A | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV54124406, COSV54125856; called by muse, mutect2, varscan2
- ALAS1 | c.757T>G p.Y253D | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59630186; called by muse, mutect2, varscan2
- ALCAM | c.547+2T>A p.X183_splice | Splice Site (SNP) | VAF 29/79 reads (37%) | catalogued as COSV60255722; called by muse, mutect2, varscan2
- ALG1L | c.361A>T p.N121Y | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV100444910; called by muse, mutect2
- ALG9 | c.790-1G>A p.X264_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV67645706; called by muse, mutect2, varscan2
- ALPK2 | c.2198T>A p.F733Y | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.25); catalogued as COSV64497786; called by muse, mutect2, varscan2
- ANAPC4 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.39); catalogued as COSV59542849; called by muse, mutect2, varscan2
- AP002748.5 | c.1610A>G p.K537R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV59152116; called by muse, varscan2
- ARHGAP4 | c.296C>G p.P99R | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100604291; called by muse, mutect2
- ASPG | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs1017467819, COSV101496458; called by muse, mutect2, varscan2
- ASPM | c.8988-1G>T p.X2996_splice | Splice Site (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99661245; called by muse, mutect2
- ASPM | c.8128A>G p.T2710A | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54139940; called by muse, mutect2, varscan2
- ATCAY | c.896T>C p.V299A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV56659688; called by muse, mutect2, varscan2
- ATG16L1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61468457; called by muse, mutect2, varscan2
- ATG2B | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV63426083; called by muse, mutect2, varscan2
- ATP12A | c.2704C>T p.R902W | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs778588362, COSV54524309; called by muse, mutect2, varscan2
- ATP13A3 | c.1765A>G p.T589A | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.179); catalogued as rs773425673, COSV55470019; called by muse, mutect2, varscan2
- ATP2C2 | c.2353G>A p.D785N | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs769535560, COSV52301999; called by muse, mutect2
- ATP8B2 | c.863T>A p.L288Q (on ENST00000672630; = p.L255Q on NM_001005855.2) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59249413; called by muse, mutect2, varscan2
- ATXN3 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV61498103; called by muse, mutect2, varscan2
- AXDND1 | c.1366A>G p.T456A | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV62649694; called by muse, mutect2, varscan2
- BARD1 | c.2027A>G p.Y676C | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs770917842, COSV53617803, COSV53618163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAS3 | c.1053G>T p.E351D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV66783107; called by muse, mutect2, varscan2
- BCCIP | c.458G>A p.C153Y | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52943787; called by muse, mutect2, varscan2
- BID | c.654C>A p.H218Q (on ENST00000317361 / NM_197966.2; = p.H172Q on NM_001196.4) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58008387; called by muse, mutect2, varscan2
- BIRC6 | c.14093T>G p.L4698R | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70206931; called by muse, mutect2, varscan2
- BOC | c.596A>T p.K199M | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV56353588, COSV56358658; called by muse, mutect2, varscan2
- BPTF | c.5981G>A p.R1994Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58848222; called by muse, mutect2, varscan2
- BRCA2 | c.1280A>G p.D427G | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs1555281813, COSV66463453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTF3L4 | c.83T>C p.V28A | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as COSV57631410; called by muse, mutect2, varscan2
- C11orf53 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.816); catalogued as COSV54722756; called by muse, mutect2, varscan2
- CABIN1 | c.5797G>C p.D1933H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54090050; called by muse, mutect2, varscan2
- CACNA1H | c.4723G>A p.E1575K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs750349354, COSV62000188; called by muse, mutect2, varscan2
- CAPN12 | c.1896C>G p.F632L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as rs754895421, COSV53150930; called by muse, mutect2, varscan2
- CASP8 | c.1305-1G>C p.X435_splice (on ENST00000432109 / NM_033355.3; = p.X452_splice on NM_001228.4) | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as rs1354563506, COSV51846662, COSV51846898, COSV51857179; called by muse, mutect2, varscan2
- CASS4 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV64388689; called by muse, mutect2, varscan2
- CAVIN2 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV58426168; called by muse, mutect2
- CCDC178 | c.1528C>T p.H510Y | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV55767065, COSV55771764; called by muse, mutect2, varscan2
- CCDC178 | c.1527C>A p.F509L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV55799970; called by muse, mutect2, varscan2
- CCDC9B | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV66876377; called by muse, mutect2, varscan2
- CCNB3 | c.3797G>A p.R1266H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147272111, COSV52070070; called by muse, mutect2
- CD86 | c.656T>C p.I219T (on ENST00000330540 / NM_175862.5; = p.I213T on NM_006889.4) | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV52610708; called by muse, mutect2, varscan2
- CDC37 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55767113, COSV55770164; called by muse, mutect2, varscan2
- CDC42 | c.151T>C p.Y51H | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.371); catalogued as rs1401679863, COSV59663874; called by muse, mutect2, varscan2
- CDKN2C | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52956072; called by muse, mutect2, varscan2
- CELA2B | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV65546399; called by muse, mutect2, varscan2
- CELSR3 | c.1748A>G p.N583S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs894448147, COSV51166004; called by muse, mutect2, varscan2
- CEP126 | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV54831494; called by muse, mutect2, varscan2
- CHD5 | c.4894C>G p.P1632A | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.011); catalogued as COSV52414277, COSV99315345; called by muse, mutect2
- CLCNKB | c.1691T>G p.L564R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV100989790; called by muse, mutect2, varscan2
- CORIN | c.467T>A p.L156Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV56700573; called by muse, mutect2, varscan2
- CORO2B | c.182G>C p.G61A | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV55958192; called by muse, mutect2, varscan2
- CPD | c.873G>C p.L291F | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56716759; called by muse, mutect2, varscan2
- CPE | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.264); catalogued as COSV68582915; called by muse, mutect2, varscan2
- CPN2 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.165); catalogued as rs763677243, COSV60470218, COSV60472268; called by muse, mutect2, varscan2
- CPT1C | c.1151C>G p.A384G | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV54922649; called by muse, mutect2, varscan2
- CRTAM | c.1180T>C p.*394Qext*8 | Nonstop Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99912342; called by muse, mutect2
- CSN1S1 | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV55890908, COSV55892440; called by muse, mutect2, varscan2
- CTBP1 | c.223A>G p.M75V | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV52076904; called by muse, mutect2, varscan2
- CTHRC1 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV57716401; called by muse, mutect2, varscan2
- CTTN | c.1349C>G p.A450G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100097181, COSV57236699; called by muse, mutect2, varscan2
- CYP27B1 | c.50_72del p.W17Sfs*308 | Frame Shift Del (DEL) | VAF 31/125 reads (25%) | catalogued as COSV57350099; called by mutect2, pindel
- CYP2A7 | c.727G>C p.G243R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.969); catalogued as COSV52507115; called by muse, mutect2, varscan2
- CYP2C19 | c.465G>C p.E155D | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV100990641; called by muse, mutect2, varscan2
- DBNDD2 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1157921315, COSV61919462; called by muse, mutect2, varscan2
- DCAF13 | c.671A>G p.Y224C | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52574861; called by muse, mutect2, varscan2
- DCTD | c.218A>C p.N73T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV63867369; called by muse, mutect2, varscan2
- DDIAS | c.1802A>C p.N601T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV61273455; called by muse, mutect2, varscan2
- DDX20 | c.2326T>C p.Y776H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63782849; called by muse, mutect2, varscan2
- DDX60L | c.2298_2314del p.T767Lfs*37 | Frame Shift Del (DEL) | VAF 28/106 reads (26%) | catalogued as COSV52723192; called by mutect2, pindel, varscan2
- DENND6B | c.1697A>T p.Y566F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV63784752; called by muse, mutect2, varscan2
- DIDO1 | c.2957C>T p.P986L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56635112; called by muse, mutect2, varscan2
- DIP2C | c.2390T>G p.M797R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV55181353, COSV99794007; called by muse, mutect2, varscan2
- DLX2 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs762543150, COSV52233088; called by muse, mutect2, varscan2
- DMAC2L | c.-5-2A>C | Splice Site (SNP) | VAF 8/47 reads (17%) | catalogued as COSV55414550; called by muse, mutect2
- DNA2 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64430466; called by muse, mutect2, varscan2
- DNAH11 | c.13194G>T p.E4398D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV60984965; called by muse, mutect2, varscan2
- DNAH17 | c.2132G>C p.R711P | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.612); catalogued as COSV101103710; called by muse, varscan2
- DNAH5 | c.10378G>A p.V3460M | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); catalogued as rs200012281; called by muse, mutect2, varscan2
- DOCK10 | c.5905G>A p.E1969K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1461824642, COSV51381071; called by muse, mutect2, varscan2
- DSG4 | c.1702G>T p.V568L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV57398442; called by muse, mutect2, varscan2
- DST | c.3062A>G p.E1021G (on ENST00000361203 / NM_001374722.1; = p.E695G on NM_001723.6) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV55043609; called by muse, mutect2, varscan2
- DTNA | c.379A>C p.I127L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV52028419; called by muse, mutect2, varscan2
- EDIL3 | c.791G>C p.G264A | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.171); catalogued as COSV56923685; called by muse, mutect2, varscan2
- EDN1 | c.501A>T p.R167S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV65081404; called by muse, mutect2, varscan2
- EIF4G1 | c.3136C>T p.L1046F (on ENST00000346169 / NM_198241.3; = p.L851F on NM_004953.5) | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as rs267599714, COSV59994591; called by muse, mutect2, varscan2
- EIF4G3 | c.1187A>T p.E396V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); catalogued as COSV51695457; called by muse, mutect2, varscan2
- EMC9 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.362); catalogued as COSV52826069; called by muse, mutect2, varscan2
- ERICH3 | c.3302A>T p.E1101V | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV58620188; called by muse, mutect2, varscan2
- ERICH5 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV59317451; called by muse, mutect2, varscan2
- FAM110B | c.660_672del p.A221Lfs*12 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as COSV64068465; called by mutect2, pindel, varscan2
- FAM199X | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.035); catalogued as COSV101534177; called by muse, mutect2
- FAM221A | c.454A>G p.S152G | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61388700; called by muse, mutect2, varscan2
- FAM234B | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV52198023; called by muse, mutect2, varscan2
- FAM241A | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59038656; called by muse, mutect2, varscan2
- FAM76A | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50550043; called by muse, mutect2, varscan2
- FAM81A | c.827T>A p.M276K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV55681071; called by muse, mutect2
- FANCL | c.10A>T p.T4S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV99288031; called by muse, varscan2
- FAT2 | c.5169C>G p.I1723M | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.602); catalogued as COSV55819249, COSV55830902; called by muse, mutect2, varscan2
- FAT4 | c.1490T>C p.I497T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV101272913; called by muse, mutect2
- FBLN1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs776925862, COSV53047324, COSV53054718; called by muse, mutect2, varscan2
- FER1L6 | c.3352A>C p.T1118P | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV67553095; called by muse, mutect2, varscan2
- FGGY | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774970699, COSV58025386, COSV58047101; called by muse, mutect2, varscan2
- FOXG1 | c.1432C>G p.Q478E | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as COSV57399938; called by muse, mutect2, varscan2
- FUZ | c.220A>G p.S74G | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs372004761; called by muse, mutect2, varscan2
- FZD7 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as rs764888077, COSV53811712; called by muse, mutect2, varscan2
- GCNA | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 83/261 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV65468477; called by muse, mutect2, varscan2
- GJA5 | c.760T>A p.S254T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54786932; called by muse, mutect2, varscan2
- GJB5 | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.656); catalogued as COSV58356508; called by muse, mutect2, varscan2
- GLG1 | c.3490A>G p.M1164V | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV52675318; called by muse, mutect2, varscan2
- GLG1 | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs964157062, COSV52665981, COSV52675328; called by muse, mutect2, varscan2
- GPCPD1 | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.339); catalogued as COSV66831933; called by muse, mutect2, varscan2
- GPR132 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV61678450; called by muse, mutect2, varscan2
- GPR37 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV58260034; called by muse, mutect2, varscan2
- GUCY1B1 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1213220279, COSV52379507; called by muse, mutect2, varscan2
- GUCY2D | c.2884A>G p.T962A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV54699236; called by muse, mutect2, varscan2
- HK2 | c.1774A>T p.K592* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99309662; called by muse, mutect2, varscan2
- HMCN1 | c.4820G>A p.R1607Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs370332057; called by muse, mutect2, varscan2
- HSPA13 | c.1288G>C p.V430L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV53466643; called by muse, mutect2, varscan2
- ILVBL | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as COSV54623222; called by muse, mutect2, varscan2
- INO80 | c.3934G>C p.D1312H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV62743099; called by muse, mutect2, varscan2
- INPP5A | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV61253729; called by muse, mutect2
- IP6K1 | c.792+1G>A p.X264_splice | Splice Site (SNP) | VAF 10/94 reads (11%) | catalogued as COSV57696853; called by muse, mutect2, varscan2
- ITGA3 | c.604A>G p.S202G | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as COSV50345645; called by muse, mutect2, varscan2
- ITGB1 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV56487375; called by muse, mutect2, varscan2
- ITGBL1 | c.1014G>A p.R338= | Splice Region (SNP) | VAF 4/13 reads (31%) | catalogued as COSV101095891, COSV66007422; called by muse, mutect2, varscan2
- KDR | c.3192T>C p.D1064= | Splice Region (SNP) | VAF 25/77 reads (32%) | catalogued as COSV55777766; called by muse, mutect2, varscan2
- KIAA0232 | c.90G>A p.M30I | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56929872; called by muse, mutect2, varscan2
- KLHDC3 | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1173576680, COSV55065862; called by muse, mutect2, varscan2
- KLHL9 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.309); catalogued as rs1477857997, COSV62922484; called by muse, mutect2, varscan2
- KLRC4 | c.44A>G p.Q15R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV58672622; called by muse, mutect2, varscan2
- KRTAP21-2 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as rs762595718, COSV61684729; called by muse, mutect2, varscan2
- LCT | c.1520A>G p.H507R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV51553383; called by muse, mutect2
- LLGL1 | c.2866G>A p.D956N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs200133079, COSV57501144; called by muse, mutect2, varscan2
- LMO7 | c.4600C>T p.Q1534* (on ENST00000357063; = p.Q1215* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100413934; called by muse, mutect2
- LRBA | c.3244A>G p.I1082V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs553088346, COSV63966276; called by muse, mutect2, varscan2
- LRRC17 | c.1076A>G p.H359R | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV50868673; called by muse, mutect2, varscan2
- MAD2L1BP | c.201A>C p.E67D | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV64679629; called by muse, mutect2, varscan2
- MALT1 | c.286A>T p.M96L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1394686223, COSV61936828; called by muse, mutect2, varscan2
- MAMDC2 | c.1973A>C p.K658T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV65860975; called by muse, mutect2, varscan2
- MAN2A2 | c.3419T>C p.M1140T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1247583198, COSV64640125; called by muse, mutect2, varscan2
- MANEA | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.204); catalogued as COSV62590751; called by muse, mutect2, varscan2
- MAP3K20 | c.2051G>T p.G684V | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as COSV64377279, COSV64380883; called by muse, mutect2, varscan2
- MAP6 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV59078171; called by muse, mutect2, varscan2
- MAP7 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs770547707, COSV63423316; called by muse, mutect2, varscan2
- MCM5 | c.1414-2A>T p.X472_splice | Splice Site (SNP) | VAF 8/39 reads (21%) | catalogued as COSV53348573; called by muse, mutect2, varscan2
- ME1 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1242884509, COSV63842950; called by muse, mutect2, varscan2
- MEGF9 | c.1006T>G p.F336V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64238153; called by muse, mutect2, varscan2
- MFAP1 | c.128A>G p.K43R | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV51041780; called by muse, mutect2, varscan2
- MIPOL1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.423); catalogued as rs762408651, COSV100539731, COSV100539807, COSV59394459; called by muse, mutect2
- MOCOS | c.2453A>G p.Q818R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54347151; called by muse, mutect2, varscan2
- MORC4 | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 38/121 reads (31%) | catalogued as COSV99717698; called by muse, mutect2, varscan2
- MRPS24 | c.440A>T p.Y147F | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV58183229; called by muse, mutect2, varscan2
- MUC16 | c.26066C>G p.T8689R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV67498214; called by mutect2, varscan2
- MUC16 | c.13298G>T p.S4433I | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as rs753224814, COSV67498218; called by muse, mutect2, varscan2
- MYO18A | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.622); catalogued as COSV62874383; called by muse, mutect2, varscan2
- NAE1 | c.1378T>C p.C460R | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51978653; called by muse, mutect2, varscan2
- NBR1 | c.2008A>G p.R670G | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV57836011; called by muse, mutect2, varscan2
- NDUFA7 | c.148T>C p.S50P | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV56847691; called by mutect2, varscan2
- NEB | c.6527A>T p.Y2176F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.992); catalogued as COSV51464611; called by muse, mutect2, varscan2
- NEFM | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1159882660, COSV99646865, COSV99647614; called by muse, mutect2, varscan2
- NELL1 | c.829G>T p.G277* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100125757; called by muse, mutect2, varscan2
- NF1 | c.1144T>C p.S382P | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV62223550; called by muse, mutect2, varscan2
- NFIL3 | c.1148T>A p.V383E | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV52684905; called by muse, mutect2, varscan2
- NGLY1 | c.188C>A p.T63N | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.502); catalogued as COSV54992016; called by muse, mutect2, varscan2
- NKX6-3 | c.671C>G p.S224W (on ENST00000518699 / NM_001364841.2; = p.S94W on NM_152568.3) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101570831, COSV72895197; called by muse, mutect2, varscan2
- NLRP11 | c.2585T>G p.L862R | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64088995; called by muse, mutect2, varscan2
- NLRP2 | c.1714A>T p.T572S | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV54761094; called by muse, mutect2, varscan2
- NOL9 | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1368687443, COSV100891417, COSV66627116; called by muse, mutect2, varscan2
- NPAP1 | c.2792C>T p.P931L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV61512086; called by muse, mutect2, varscan2
- NPR1 | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV64118227; called by muse, mutect2, varscan2
- NRK | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV54608238; called by muse, mutect2, varscan2
- NYNRIN | c.395A>T p.N132I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as COSV66845469; called by muse, mutect2, varscan2
- OGDH | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs775737016, COSV56057953; called by muse, mutect2, varscan2
- OMA1 | c.1343A>G p.Y448C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.518); catalogued as COSV62257057; called by muse, mutect2, varscan2
- OMD | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV65020548; called by muse, mutect2, varscan2
- OPHN1 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV62787599; called by muse, mutect2, varscan2
- OR1F1 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.218); catalogued as COSV58962685; called by muse, mutect2, varscan2
- OR2A12 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV68822136; called by muse, mutect2, varscan2
- OR2AK2 | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63562275; called by muse, mutect2, varscan2
- OR2T10 | c.644C>A p.S215* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | catalogued as COSV100393834; called by muse, mutect2, varscan2
- OR8B4 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.765); catalogued as rs752372117, COSV62070702; called by muse, mutect2, varscan2
- PABPC3 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV55806917; called by mutect2, varscan2
- PAK3 | c.426T>A p.D142E (on ENST00000262836 / NM_001324328.2; = p.D127E on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); catalogued as COSV53281270; called by muse, mutect2, varscan2
- PCIF1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV65027346; called by muse, mutect2, varscan2
- PCNT | c.2443A>G p.T815A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV64033585; called by mutect2, varscan2
- PEX3 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV62569656; called by muse, mutect2, varscan2
- PHLPP2 | c.1973C>T p.T658I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs914996961, COSV62427523; called by muse, mutect2, varscan2
- PI4K2B | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV53513292; called by muse, mutect2, varscan2
- PICALM | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV62674609; called by muse, mutect2, varscan2
- PICALM | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62670310, COSV62674623; called by muse, mutect2, varscan2
- PIK3R3 | c.1133G>C p.G378A | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53108957, COSV53111652; called by muse, mutect2, varscan2
- PKIA | c.67A>G p.I23V | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV61917190; called by muse, mutect2, varscan2
- PLCB2 | c.871A>G p.M291V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV53038607; called by muse, mutect2, varscan2
- PLCH2 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760790950, COSV53941362; called by muse, mutect2, varscan2
- POLQ | c.1764G>A p.W588* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV99953119; called by muse, mutect2, varscan2
- PPARGC1A | c.14T>A p.M5K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.035); catalogued as COSV53534184; called by muse, mutect2, varscan2
- PRPF3 | c.1878A>C p.K626N | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV61396607; called by muse, mutect2, varscan2
- PRR14 | c.193-2A>T p.X65_splice | Splice Site (SNP) | VAF 10/38 reads (26%) | catalogued as COSV54913965; called by muse, mutect2, varscan2
- PRSS36 | c.1529C>G p.S510W | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51640170; called by muse, mutect2, varscan2
- PSG6 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV51838801; called by muse, mutect2, varscan2
- PTPRM | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV59857868, COSV59883906; called by muse, mutect2, varscan2
- PUS7L | c.661T>C p.Y221H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61263064; called by muse, mutect2, varscan2
- PWWP2B | c.281C>G p.P94R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100535955; called by muse, mutect2, varscan2
- RAB14 | c.107-2A>C p.X36_splice | Splice Site (SNP) | VAF 14/57 reads (25%) | catalogued as COSV65788817; called by muse, mutect2, varscan2
- RAB25 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100737422; called by muse, mutect2, varscan2
- RASSF5 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs782799384, COSV62427642; called by muse, mutect2, varscan2
- RB1 | c.2559T>A p.C853* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV57301205; called by muse, mutect2, varscan2
- RBM26 | c.2909A>T p.E970V (on ENST00000438737 / NM_001366735.2; = p.E943V on NM_022118.5) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57400436; called by muse, mutect2, varscan2
- RBM6 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV56487420, COSV56488765; called by muse, mutect2, varscan2
- RBM6 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV56482713, COSV56488774; called by muse, mutect2, varscan2
- RGS12 | c.1924C>T p.Q642* | Nonsense Mutation (SNP) | VAF 59/155 reads (38%) | catalogued as COSV100137123; called by muse, mutect2, varscan2
- RIPK4 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768158256, COSV60185763; called by muse, mutect2, varscan2
- ROBO2 | c.2989T>C p.Y997H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59942705; called by muse, mutect2, varscan2
- RPAIN | c.260A>T p.E87V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as rs781557194, COSV56708232; called by muse, mutect2, varscan2
- RSPH6A | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as rs762679225, COSV55572473; called by muse, mutect2, varscan2
- RUNDC3B | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.78); catalogued as COSV100407356, COSV56693084; called by muse, mutect2
- SBDS | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as COSV55888309; called by muse, mutect2, varscan2
- SCML1 | c.976T>C p.C326R (on ENST00000380041 / NM_001037540.3; = p.C299R on NM_006746.6) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1489075055, COSV66241068; called by muse, mutect2, varscan2
- SCN1A | c.4046A>G p.N1349S (on ENST00000303395 / NM_001202435.3; = p.N1338S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57690299; called by muse, mutect2, varscan2
- SEC16B | c.188G>T p.R63M | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV57630574; called by muse, mutect2, varscan2
- SEL1L3 | c.2398T>C p.Y800H | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.376); catalogued as COSV53550526; called by muse, mutect2, varscan2
- SEPTIN10 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1415907303, COSV61782322; called by muse, mutect2, varscan2
- SGMS2 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs766967019, COSV62989871; called by muse, mutect2, varscan2
- SIGLEC6 | c.460G>T p.G154W | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58437861; called by muse, mutect2, varscan2
- SIX4 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.789); catalogued as COSV53671763; called by muse, mutect2, varscan2
- SLAMF6 | c.213A>T p.K71N | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.089); catalogued as COSV63588371; called by muse, mutect2, varscan2
- SLC24A4 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV54122444; called by muse, mutect2
- SLC26A8 | c.1010A>C p.D337A | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV62887900; called by muse, mutect2, varscan2
- SLC29A4 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99787014; called by muse, varscan2
- SLC40A1 | c.1614T>A p.Y538* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99656578; called by muse, mutect2, varscan2
- SLC6A2 | c.1831-1G>T p.X611_splice | Splice Site (SNP) | VAF 14/41 reads (34%) | catalogued as COSV54924223; called by muse, mutect2, varscan2
- SLC9C1 | c.1898T>A p.I633K | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs760004235, COSV59894200; called by muse, mutect2, varscan2
- SMAD4 | c.1234T>G p.Y412D | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV61695585; called by muse, mutect2, varscan2
- SMC5 | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.317); catalogued as COSV63195841; called by muse, mutect2, varscan2
- SORD | c.70A>T p.N24Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV51045493; called by muse, mutect2, varscan2
- SPATA5 | c.1702T>C p.C568R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56785508; called by muse, mutect2, varscan2
- SPEF2 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs759006049, COSV56794738, COSV56799909; called by muse, mutect2, varscan2
- SPG11 | c.2726A>G p.Y909C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1486619427, COSV56002940; called by muse, mutect2, varscan2
- SPTA1 | c.5571G>T p.L1857F | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV100935687; called by muse, mutect2
- SPTBN2 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226702717, COSV100020651; called by muse, mutect2, varscan2
- SSBP4 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54212706; called by mutect2, varscan2
- STAG2 | c.2550T>A p.D850E | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.175); catalogued as COSV54370910, COSV54374140; called by muse, mutect2, varscan2
- STAG2 | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV99495645; called by muse, mutect2, varscan2
- STIP1 | c.1531A>G p.M511V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV54184234; called by muse, mutect2, varscan2
- STK39 | c.964C>G p.P322A | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV63601177, COSV63601608; called by muse, mutect2, varscan2
- STOM | c.671C>A p.A224D | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54419615; called by muse, mutect2, varscan2
- SUN1 | c.1727C>T p.S576L (on ENST00000405266 / NM_001367651.1; = p.S456L on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1299756990, COSV67452224; called by muse, mutect2, varscan2
- SYBU | c.1313G>A p.S438N (on ENST00000276646 / NM_001099754.2; = p.S437N on NM_017786.6) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV52623529; called by muse, mutect2, varscan2
- TAZ | c.117G>T p.M39I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs1557191054, COSV50011342, COSV99186184; called by muse, mutect2, varscan2
- TBC1D8B | c.240T>A p.C80* | Nonsense Mutation (SNP) | VAF 28/89 reads (31%) | catalogued as COSV99345144; called by muse, mutect2, varscan2
- TBCD | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV62808740; called by muse, mutect2, varscan2
- TBX22 | c.890C>A p.T297N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV64788127; called by muse, mutect2, varscan2
- TCEA2 | c.384T>G p.F128L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV100180919; called by muse, mutect2
- TCF12 | c.1973C>G p.S658W | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1235111709, COSV51006267, COSV51028497; called by muse, mutect2, varscan2
- TCF25 | c.840G>C p.Q280H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.676); catalogued as COSV54533557; called by muse, mutect2, varscan2
- TCHH | c.1922A>G p.E641G | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV64278132; called by muse, mutect2, varscan2
- TCHHL1 | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1423366554, COSV64287901; called by muse, mutect2, varscan2
- TCHP | c.505C>A p.Q169K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1361426157, COSV57166751; called by muse, mutect2
- TDGF1 | c.61A>C p.K21Q | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as COSV56129130; called by muse, mutect2, varscan2
- TDRD7 | c.685T>G p.S229A | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV62429719, COSV62431228; called by muse, mutect2, varscan2
- TFRC | c.950A>G p.N317S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs374173098, COSV104420013, COSV64056901; called by muse, mutect2, varscan2
- TGOLN2 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 101/581 reads (17%) | catalogued as COSV99965172; called by muse, mutect2, varscan2
- THTPA | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs748307957, COSV55339806; called by muse, mutect2, varscan2
- TMEM248 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV58578614; called by muse, mutect2, varscan2
- TOP2A | c.4448C>T p.S1483L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); catalogued as rs777338287, COSV68502976; called by muse, mutect2
- TOX3 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54874199; called by muse, mutect2, varscan2
- TP53TG5 | c.224G>T p.S75I | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV65578363; called by muse, mutect2, varscan2
- TRERF1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 31/50 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV61678768; called by muse, mutect2, varscan2
- TREX2 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as rs782755741, COSV100443935, COSV57849083; called by muse, mutect2, varscan2
- TRIP12 | c.4838G>T p.R1613L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV52264159, COSV52273703; called by muse, mutect2, varscan2
- TRPC5 | c.2290A>T p.R764* | Nonsense Mutation (SNP) | VAF 42/299 reads (14%) | catalogued as COSV99463004; called by muse, mutect2, varscan2
- TRRAP | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV62855514; called by muse, mutect2, varscan2
- TSPAN1 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as rs1244287337, COSV64341123; called by muse, mutect2, varscan2
- TTLL12 | c.1009A>C p.N337H | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV53357359, COSV53357623; called by muse, mutect2, varscan2
- TTLL3 | c.788A>T p.E263V | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV59616037; called by muse, mutect2, varscan2
- TTLL9 | c.318+1G>A p.X106_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | catalogued as COSV60597053; called by muse, mutect2
- TTN | c.22591G>C p.D7531H (on ENST00000591111; = p.D6604H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | PolyPhen possibly damaging (0.667); catalogued as COSV60385302; called by muse, mutect2, varscan2
- TTYH1 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as rs1253348898, COSV100001799; called by muse, mutect2, varscan2
- TXLNG | c.1196G>A p.W399* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV100418003; called by muse, mutect2, varscan2
- UCHL3 | c.389G>T p.S130I | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV66460694; called by muse, mutect2, varscan2
- UGGT2 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs910023686, COSV100948976; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2719T>C p.S907P | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV54443263; called by muse, mutect2, varscan2
- UNC79 | c.1334C>A p.A445D (on ENST00000393151 / NM_001346218.2; = p.A268D on NM_020818.5) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as rs372496746; called by muse, mutect2
- USP7 | c.1945A>G p.I649V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV61217842; called by muse, mutect2, varscan2
- VASN | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756410464, COSV52034537; called by muse, mutect2, varscan2
- WDR3 | c.2464G>C p.E822Q | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV60469592; called by muse, mutect2, varscan2
- WIPF2 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as COSV60274592, COSV60276247; called by muse, mutect2, varscan2
- YBX3 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54387234; called by muse, mutect2, varscan2
- ZIC4 | c.673A>G p.K225E | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV67174354; called by muse, mutect2, varscan2
- ZNF17 | c.415A>G p.S139G | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100300143, COSV56922670; called by muse, mutect2, varscan2
- ZNF180 | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55422734; called by muse, mutect2
- ZNF326 | c.61+1G>C p.X21_splice | Splice Site (SNP) | VAF 5/52 reads (10%) | catalogued as COSV61036839; called by muse, mutect2
- ZNF341 | c.149A>T p.E50V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV61011519; called by muse, mutect2, varscan2
- ZNF383 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as COSV100776801; called by muse, mutect2, varscan2
- ZNF571 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.312); catalogued as COSV60734803; called by muse, mutect2, varscan2
- ZNF749 | c.709T>C p.S237P | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV61948551; called by muse, mutect2
- ZNF880 | c.662T>C p.F221S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69906972; called by muse, mutect2, varscan2
- ZNF99 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV68055646, COSV68057222; called by muse, mutect2, varscan2
- CD180 | c.1373_1388del p.D458Vfs*3 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | called by mutect2, pindel*, varscan2*
- GOLGA2 | c.1630_1635del p.F544_V545del | In Frame Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel
- H2AC14 | c.239_254del p.I80Sfs*? | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | called by mutect2, pindel, varscan2
- IGKV3-15 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR5L1 | c.166del p.H56Tfs*14 | Frame Shift Del (DEL) | VAF 41/189 reads (22%) | called by mutect2, pindel, varscan2
- RASA2 | c.509G>A p.C170Y | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2
- RERE | c.3412_3439del p.D1138Qfs*110 | Frame Shift Del (DEL) | VAF 11/89 reads (12%) | called by mutect2, pindel
- RNFT2 | c.799_811del p.D267Sfs*34 | Frame Shift Del (DEL) | VAF 36/98 reads (37%) | called by mutect2, pindel, varscan2
- RPS6KA3 | c.2099_2100+21del p.X700_splice | Splice Site (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel
- SRRT | c.61_63del p.S21del | In Frame Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- TRAV21 | c.280T>G p.L94V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TRAV29DV5 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBR4 | c.4261_4291del p.A1421Sfs*7 | Frame Shift Del (DEL) | VAF 14/138 reads (10%) | called by mutect2, pindel
- AARS2 | c.727C>T p.L243= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs766228163, COSV55117877; called by muse, mutect2, varscan2
- ADGRL2 | c.1191T>C p.P397= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs1207376423, COSV54691936; called by muse, mutect2, varscan2
- ADSS2 | c.528G>T p.R176= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100836923; called by muse, mutect2
- AKTIP | c.849C>T p.F283= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV50890365; called by muse, mutect2, varscan2
- ANXA6 | c.669G>A p.G223= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV62908625; called by muse, mutect2, varscan2
- APBB1IP | c.1110T>C p.H370= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs1256278663, COSV66136805; called by muse, mutect2, varscan2
- ARAP2 | c.3879T>C p.Y1293= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV58293261; called by muse, mutect2, varscan2
- ARHGEF11 | c.57A>G p.G19= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs1419981080, COSV63815933; called by muse, mutect2, varscan2
- ARSL | c.1053G>A p.T351= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs776633099, COSV66966077; called by muse, mutect2, varscan2
- ATG4A | c.795T>C p.Y265= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV58967252, COSV58967744; called by muse, mutect2, varscan2
- ATP1A4 | c.1113G>A p.A371= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs372583572; called by muse, mutect2, varscan2
- AVPR1B | c.63T>C p.N21= | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as COSV65638753; called by muse, mutect2, varscan2
- BLM | c.2478G>T p.V826= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV61922849, COSV61927880; called by muse, mutect2, varscan2
- BPI | c.375A>G p.Q125= (on ENST00000262865; = p.Q121= on NM_001725.3) | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV53408799; called by muse, mutect2, varscan2
- C11orf68 | c.441C>T p.A147= (on ENST00000530188; = p.A188= on NM_031450.4) | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV100437190; called by muse, mutect2
- CA7 | c.136C>T p.L46= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100623831; called by muse, mutect2
- CAMTA2 | c.1755C>T p.C585= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV61838676; called by muse, mutect2, varscan2
- CCDC173 | c.717T>C p.D239= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs768892227, COSV69573811; called by muse, mutect2, varscan2
- CCDC9B | c.1455A>G p.P485= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs372988249, COSV66876382; called by muse, mutect2, varscan2
- CEACAM6 | c.612C>T p.S204= | Silent (SNP) | VAF 75/224 reads (33%) | catalogued as rs781826090, COSV52269589; called by muse, mutect2, varscan2
- CEP126 | c.2709G>A p.A903= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as rs778171900, COSV54831506; called by muse, mutect2, varscan2
- CHD4 | c.69T>G p.L23= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV58911996; called by muse, mutect2, varscan2
- CHST6 | c.909C>T p.I303= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV60001897; called by muse, mutect2, varscan2
- CLTCL1 | c.4344G>T p.V1448= | Silent (SNP) | VAF 45/139 reads (32%) | catalogued as COSV54240398; called by muse, mutect2, varscan2
- COL12A1 | c.8397C>T p.L2799= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV59394108; called by muse, mutect2, varscan2
- CPA5 | c.1212T>C p.Y404= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV62570949; called by muse, mutect2, varscan2
- DGKB | c.774C>T p.C258= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs764637334, COSV51780935, COSV51799999; called by muse, mutect2, varscan2
- DGKQ | c.2610G>A p.R870= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as rs1428283249, COSV99298289; called by muse, mutect2, varscan2
- DOCK11 | c.5839T>C p.L1947= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV52248577; called by muse, mutect2, varscan2
- DPAGT1 | c.81C>G p.T27= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV62615305; called by muse, mutect2, varscan2
- DPYS | c.315G>A p.Q105= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs779151774, COSV60914150; called by muse, mutect2, varscan2
- DQX1 | c.540T>C p.D180= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV66353706; called by muse, mutect2, varscan2
- DRD1 | c.1287C>T p.D429= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as rs200809329; called by muse, mutect2, varscan2
- DUOX2 | c.4293C>T p.D1431= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV66535079; called by muse, mutect2
- DYNC2H1 | c.10875C>T p.A3625= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs745497465, COSV62108330; called by muse, varscan2
- EEPD1 | c.1434C>T p.I478= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV54203669; called by muse, mutect2, varscan2
- EHBP1 | c.1083T>A p.T361= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV50420896, COSV50442077; called by muse, mutect2, varscan2
- ELSPBP1 | c.21C>T p.Y7= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs1176844403, COSV60415249; called by muse, mutect2, varscan2
- EME1 | c.1221C>T p.D407= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as rs1475431709, COSV56815711; called by muse, mutect2, varscan2
- EPHX3 | c.1062C>T p.F354= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV55656196, COSV55656847; called by muse, mutect2, varscan2
- FAF1 | c.870T>C p.D290= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV65644619; called by muse, mutect2, varscan2
- FAIM2 | c.630C>T p.T210= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs139044559; called by muse, mutect2, varscan2
- FCGBP | c.4716C>T p.F1572= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV99664425; called by muse, mutect2, varscan2
- FOSL2 | c.18C>T p.P6= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99268369, COSV99268575; called by muse, varscan2
- GPR137B | c.387C>G p.L129= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV63991816; called by muse, mutect2, varscan2
- HMGCL | c.744C>A p.A248= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV52527601; called by muse, mutect2, varscan2
- IFT43 | c.405G>A p.L135= (on ENST00000314067 / NM_001102564.3; = p.L140= on NM_052873.3) | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV53141900; called by muse, mutect2, varscan2
- IFT74 | c.870A>G p.Q290= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs759949842, COSV66289016; called by muse, mutect2, varscan2
- IL13RA2 | c.66T>C p.C22= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as COSV54567816; called by muse, mutect2, varscan2
- IL36RN | c.381C>T p.A127= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs760489144, COSV61011016; called by muse, mutect2, varscan2
- ITGB8 | c.612C>T p.P204= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs756469815, COSV56015175; called by muse, mutect2
- ITGB8 | c.1719A>G p.Q573= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1167401303, COSV56015191; called by mutect2, varscan2
- ITIH6 | c.3216C>T p.S1072= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV54495398; called by muse, mutect2, varscan2
- KCNA10 | c.831C>T p.T277= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs369545748; called by muse, mutect2, varscan2
- KCNH2 | c.177G>A p.V59= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs753837732, COSV51235075; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIAA1109 | c.687T>C p.D229= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV52695565; called by muse, mutect2, varscan2
- KIF27 | c.3519C>T p.H1173= | Silent (SNP) | VAF 51/117 reads (44%) | catalogued as rs144826636, COSV52830240; called by muse, mutect2, varscan2
- KNL1 | c.552T>C p.T184= (on ENST00000346991 / NM_170589.5; = p.T158= on NM_144508.5) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV61160969; called by muse, mutect2, varscan2
- KRT32 | c.498G>A p.R166= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV56788481; called by muse, mutect2, varscan2
- KXD1 | c.444C>T p.G148= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs1051429071, COSV55890614; called by muse, mutect2, varscan2
- LARP4 | c.957C>T p.V319= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV53327510; called by muse, mutect2, varscan2
- LILRA2 | c.132T>A p.P44= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as COSV52197806; called by muse, mutect2, varscan2
- LRRC8D | c.924T>C p.Y308= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV61581495; called by muse, mutect2, varscan2
- LRRCC1 | c.2478T>C p.I826= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as COSV64486179; called by muse, mutect2, varscan2
- MAP3K2 | c.408A>G p.L136= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs1197156013, COSV61296613; called by muse, mutect2
- MAPK4 | c.609C>T p.P203= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV101246050; called by muse, mutect2
- MCF2 | c.1545T>C p.Y515= | Silent (SNP) | VAF 39/162 reads (24%) | catalogued as COSV58496113; called by muse, mutect2, varscan2
- MST1R | c.894C>T p.L298= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as rs369687896, COSV56576501; called by muse, mutect2, varscan2
- MSTN | c.81T>C p.S27= | Silent (SNP) | VAF 44/128 reads (34%) | catalogued as rs1444614625, COSV53622438; called by muse, mutect2, varscan2
- MTR | c.3177A>T p.I1059= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV63966493; called by muse, mutect2, varscan2
- MXRA5 | c.3774C>T p.S1258= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as COSV54252733; called by muse, mutect2, varscan2
- MYO5B | c.114A>G p.L38= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV53218732; called by muse, mutect2, varscan2
- NEBL | c.1050A>T p.P350= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV65805996, COSV65806254; called by muse, mutect2, varscan2
- NLGN1 | c.2052A>G p.A684= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV64348478; called by muse, mutect2, varscan2
- NLRP8 | c.1053C>T p.L351= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs267605703, COSV52585055; called by muse, mutect2, varscan2
- NRP2 | c.1167T>C p.D389= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV55936252; called by muse, mutect2, varscan2
- NT5C2 | c.936G>A p.L312= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV58419708; called by muse, mutect2, varscan2
- OBSCN | c.17772C>T p.L5924= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs367899115; called by muse, mutect2, varscan2
- PCDHAC2 | c.480G>A p.S160= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV53872717; called by muse, mutect2, varscan2
- PDE1A | c.54T>C p.Y18= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs1305234506, COSV59538552; called by muse, mutect2, varscan2
- PDGFC | c.9C>T p.L3= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs896118748, COSV56855870; called by muse, mutect2, varscan2
- PHTF2 | c.810A>T p.S270= (on ENST00000248550 / NM_001366089.1; = p.S232= on NM_020432.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV50342708; called by muse, mutect2, varscan2
- PLA2G4F | c.1857C>A p.S619= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs781598817, COSV51829784; called by muse, mutect2, varscan2
- PLAUR | c.726T>C p.N242= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV55391885; called by muse, mutect2, varscan2
- PLEC | c.8733C>T p.V2911= (on ENST00000322810 / NM_201380.4; = p.V2801= on NM_000445.5) | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV59701787; called by muse, mutect2, varscan2
- PLEKHA6 | c.1905C>G p.L635= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV55340982; called by muse, mutect2, varscan2
- PLXNA2 | c.3981G>A p.P1327= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs765926049, COSV65445502; called by muse, mutect2, varscan2
- PPP1CB | c.753A>G p.E251= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV56092203; called by muse, mutect2, varscan2
- PPP2R1B | c.42G>A p.A14= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV59537123; called by muse, mutect2, varscan2
- PPP2R5B | c.1152G>A p.E384= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV51213867; called by muse, mutect2, varscan2
- PRDM9 | c.2397A>C p.T799= | Silent (SNP) | VAF 46/160 reads (29%) | catalogued as COSV57014121; called by muse, varscan2
- PRLHR | c.138C>A p.A46= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs1269775744, COSV53305394; called by muse, mutect2, varscan2
- PRX | c.2748G>T p.G916= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV52533974; called by muse, mutect2, varscan2
- RBIS | c.210T>G p.L70= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV56276581; called by muse, mutect2
- RPS19BP1 | c.171G>A p.K57= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV58180593; called by muse, mutect2, varscan2
- RSRP1 | c.810A>G p.A270= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV54563287; called by muse, mutect2, varscan2
- RUFY3 | c.810G>A p.L270= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as rs781151980, COSV56917932; called by muse, mutect2, varscan2
- SAGE1 | c.1827A>G p.A609= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as rs1322028070, COSV61018753; called by muse, mutect2, varscan2
- SCN3A | c.741T>C p.L247= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV51826259; called by muse, mutect2, varscan2
- SEC14L5 | c.1678C>T p.L560= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs374590239, COSV52039388, COSV52042480; called by muse, mutect2, varscan2
- SERPINB8 | c.939T>G p.V313= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99729440; called by muse, mutect2
- SFSWAP | c.2170C>T p.L724= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV55526384; called by muse, mutect2, varscan2
- SGSM1 | c.2158C>T p.L720= (on ENST00000400359 / NM_001039948.4; = p.L659= on NM_133454.3) | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV68514113; called by muse, mutect2, varscan2
- SLC38A7 | c.1128C>T p.V376= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV54705068; called by muse, mutect2, varscan2
- SLC44A3 | c.468A>G p.P156= (on ENST00000271227 / NM_001114106.3; = p.P108= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV54734327; called by muse, mutect2, varscan2
- SLC4A10 | c.2790G>A p.L930= (on ENST00000446997 / NM_001354461.2; = p.L900= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV55802235; called by muse, mutect2, varscan2
- SNURF | c.189C>T p.F63= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV57601013; called by muse, mutect2, varscan2
- SPAG9 | c.174G>T p.L58= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100006126; called by muse, mutect2
- SPAM1 | c.1320C>G p.T440= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV56148486; called by muse, mutect2, varscan2
- SRPK3 | c.240C>T p.H80= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs782626255, COSV54208850; called by muse, mutect2, varscan2
- SULT2B1 | c.399G>A p.K133= (on ENST00000201586 / NM_177973.2; = p.K118= on NM_004605.2) | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV52379091; called by muse, mutect2, varscan2
- TBC1D15 | c.729T>C p.Y243= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs758390675, COSV59853463; called by muse, mutect2, varscan2
- TCEA2 | c.588G>C p.L196= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV58659627; called by muse, mutect2, varscan2
- TCEAL8 | c.174C>T p.G58= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV63506641; called by muse, mutect2, varscan2
- TIAM2 | c.963A>G p.E321= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV59705177; called by muse, mutect2, varscan2
- TLN2 | c.7257C>T p.H2419= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs369147646; called by muse, mutect2, varscan2
- TNFAIP2 | c.870C>T p.I290= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1253513704, COSV60696459; called by muse, mutect2, varscan2
- TOP2B | c.2682G>T p.V894= (on ENST00000264331 / NM_001330700.2; = p.V889= on NM_001068.3) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV51977865; called by muse, mutect2, varscan2
- TRGV9 | c.255G>A p.P85= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs976543421; called by muse, mutect2, varscan2
- TTC13 | c.1539G>C p.L513= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV64170326; called by muse, mutect2, varscan2
- TXNIP | c.705A>G p.S235= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs1553766117, COSV65221555; called by muse, mutect2, varscan2
- UBE4B | c.1755G>T p.L585= (on ENST00000343090 / NM_001105562.3; = p.L456= on NM_006048.5) | Silent (SNP) | VAF 63/185 reads (34%) | catalogued as COSV53538910; called by muse, mutect2, varscan2
- URGCP | c.576C>T p.L192= (on ENST00000453200 / NM_001077663.3; = p.L183= on NM_017920.4) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV56253388; called by muse, mutect2, varscan2
- UTRN | c.5775A>T p.A1925= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV62349425; called by muse, mutect2
- VPS13D | c.11580C>T p.H3860= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV50697156; called by muse, mutect2, varscan2
- WARS1 | c.819C>T p.D273= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV59927945; called by muse, mutect2, varscan2
- WDFY3 | c.9222A>G p.E3074= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV55715267; called by muse, mutect2, varscan2
- ZBTB38 | c.1797A>C p.A599= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV58544646; called by muse, mutect2, varscan2
- ZCCHC2 | c.3141A>T p.S1047= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV54041574; called by muse, mutect2, varscan2
- ARMC5 | c.1864+170A>G | Intron (SNP) | VAF 14/29 reads (48%) | catalogued as rs772402693, COSV51660317; called by muse, mutect2, varscan2
- C8orf86 | n.527_543del | RNA (DEL) | VAF 12/38 reads (32%) | catalogued as COSV63935797; called by mutect2, pindel, varscan2
- CHAT | c.287-413G>T | Intron (SNP) | VAF 27/80 reads (34%) | catalogued as COSV60334271; called by muse, mutect2, varscan2
- CTBP1 | chr4:1250830 G>A | 5'Flank (SNP) | VAF 15/44 reads (34%) | catalogued as rs764740845; called by muse, mutect2, varscan2
- CTSL3P | n.578G>A | RNA (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- DST-AS1 | n.139+7492T>C | Intron (SNP) | VAF 7/33 reads (21%) | catalogued as COSV66109399; called by muse, mutect2, varscan2
- GPS1 | c.33+414T>C | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as rs1395245973, COSV100136165; called by muse, mutect2, varscan2
- HEPACAM2 | c.-2G>A | 5'UTR (SNP) | VAF 7/32 reads (22%) | catalogued as rs756526681, COSV101085701; called by muse, mutect2, varscan2
- MIA2 | c.1887+50A>G | Intron (SNP) | VAF 16/69 reads (23%) | catalogued as COSV54486943; called by muse, mutect2, varscan2
- SPTLC1 | c.427+453G>A | Intron (SNP) | VAF 8/75 reads (11%) | catalogued as COSV99365227; called by muse, mutect2, varscan2
- TRIM61 | c.526-2147A>G | Intron (SNP) | VAF 5/18 reads (28%) | catalogued as rs1392157776, COSV61419038; called by muse, mutect2
- ZMYM5 | c.1038+105T>C | Intron (SNP) | VAF 52/159 reads (33%) | catalogued as COSV61990318; called by muse, mutect2, varscan2
